Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3325, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3325-01A (Primary Tumor).

[page 1 of 2]
MRN: [REDACTED]
[REDACTED] IP
[REDACTED] MD
Age: [REDACTED] Sex: [REDACTED]
DOB: [REDACTED]

[REDACTED] Hospital
[REDACTED]
[REDACTED]
Laboratory Patient Report
Print Date/Time: [REDACTED]

Surgical Pathology

Histopathological Examination

Path#: [REDACTED]
Collected: [REDACTED] Received: [REDACTED] Complete [REDACTED]

Pre-Op Diagnosis : Renal Cell Cancer
Order Physician : [REDACTED] MD
Specimens : Kidney, right kidney [REDACTED]
Frozen Diagnosis :

Report : GROSS EXAMINATION:
The specimen is received in a container labeled with the name of the patient and labeled as kidney, right. The specimen consists of a kidney and attached perinephric fat which measures en bloc 18 x 12 x 6 cm and weighs 597 g. The ureter and vascular margins of resection are submitted in block 1. Sectioning into the kidney shows an oval golden yellow mass in the lower mid portion of the kidney which measures 3.3 x 3.2 x 2.7 cm. The mass bulges against the capsule but is not adherent to the capsule. Sections of the capsule overlying the mass are submitted in block 2. Sections of the mass are submitted in blocks 3-7. The cortex averages 0.8 cm. The pelvis and calyces are not grossly dilated. A random section of kidney is submitted in block 8. Sectioning through the attached fat shows a portion of adrenal gland which measures 3.5 x 1.5 x 0.5 cm. This tissue is totally submitted in blocks 9-10. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

SPECIMEN TYPE: Radical nephrectomy.
LATERALITY: Right.
TUMOR SITE: Lower mid pole.
FOCALITY: Unifocal.
TUMOR SIZE (LARGEST TUMOR IF MULTIPLE): 3.3 cm.
Additional dimensions: 3.2 x 2.7 cm.
MACROSCOPIC EXTENT OF TUMOR: Tumor is limited to the kidney.

HISTOLOGIC TYPE: Clear cell (conventional) renal cell carcinoma.
HISTOLOGIC GRADE: FUHRMAN NUCLEAR GRADE II.
EXTENT OF INVASION
PRIMARY TUMOR (PT): pT1a
REGIONAL LYMPH NODES (PN): pNX: Cannot be assessed

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#: [REDACTED]
Path #: [REDACTED]
Visit #: [REDACTED]

[page 2 of 2]
DISTANT METASTASIS (PM): pMX: Cannot be assessed
MARGINS: Uninvolved by invasive carcinoma including
ureteral, renal vein, and renal capsule.
ADRENAL GLAND: Uninvolved by tumor.
VENOUS (LARGE VESSEL) INVASION (V): Absent.
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent.
ADDITIONAL PATHOLOGIC FINDINGS: None identified.

Intradepartmental consultation obtained.
Pathologic staging summary: pT1a,pNX,pMX.

[REDACTED], M.D.
Pathologist

[REDACTED]
[T-71000 M-83103 189.0 P3-44070]

Electronically Signed by:
[REDACTED], MD

[REDACTED]

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#: [REDACTED] Path # [REDACTED]
Visit #: [REDACTED]

Page 2 of 2

Source: NCI Genomic Data Commons file 12d9e4fc-adeb-403c-a065-c09f6b14761d (TCGA-A3-3325.71137006-20BE-4C81-B7A0-C315286DDC25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).